Somatic mutation profile of tumor specimen 0DUB82 from CCDI case PBCKBL, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 10.0 years (3,667 days).
Specimen 0DUB82: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8cab188b-870f-4917-a067-486113609752.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DUB66 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/86b59f76-d8e3-42a2-b408-0f9e90dd097a

The open-access MAF lists 21 somatic variants for this specimen: 11 protein-altering or splice-affecting, 5 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 5, 3'UTR 2, Intron 2, Nonsense Mutation 1, RNA 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTCH1 | c.1804C>T p.R602* | Nonsense Mutation (SNP) | VAF 216/329 reads (66%) | catalogued as rs863224650, CM066203, COSV59462369, COSV59487305; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SMARCA4 | c.3403C>T p.R1135W | Missense Mutation (SNP) | VAF 56/369 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60795621; called by muse, mutect2, varscan2
- SMARCA4 | c.3575G>A p.R1192H | Missense Mutation (SNP) | VAF 101/424 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60785906, COSV60794673; called by muse, mutect2, varscan2
- DST | c.316C>T p.R106C | Missense Mutation (SNP) | VAF 218/642 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as rs183558657, COSV56808337; called by muse, mutect2, varscan2
- KAT2A | c.1697G>A p.R566H | Missense Mutation (SNP) | VAF 168/393 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs561786361, COSV52424964; called by muse, mutect2, varscan2
- PIK3C3 | c.400G>A p.G134S | Missense Mutation (SNP) | VAF 119/354 reads (34%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.506); catalogued as rs138532795; called by muse, mutect2, varscan2
- SPON1 | c.649G>A p.E217K | Missense Mutation (SNP) | VAF 50/680 reads (7%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.854); catalogued as rs577085002; called by muse, mutect2
- AEBP2 | c.1226G>A p.R409Q | Missense Mutation (SNP) | VAF 40/728 reads (5%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.978); called by muse, mutect2
- FMO4 | c.142A>G p.K48E | Missense Mutation (SNP) | VAF 189/455 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HIC2 | c.1649_1650insC p.H551Sfs*15 | Frame Shift Ins (INS) | VAF 29/145 reads (20%) | called by mutect2, varscan2
- ZNF354C | c.1408T>C p.C470R | Missense Mutation (SNP) | VAF 265/655 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CELF1 | c.807T>A p.A269= (on ENST00000358597 / NM_001376422.1; = p.A265= on NM_006560.4 and 10 other RefSeq transcripts) | Silent (SNP) | VAF 20/260 reads (8%) | catalogued as rs1167537044; called by muse, mutect2
- FCGBP | c.4194G>A p.K1398= | Silent (SNP) | VAF 21/186 reads (11%) | called by muse, mutect2, varscan2
- OR8H3 | c.405T>C p.I135= | Silent (SNP) | VAF 119/534 reads (22%) | called by muse, mutect2, varscan2
- RREB1 | c.2496C>T p.G832= | Silent (SNP) | VAF 23/159 reads (14%) | catalogued as rs774824920; called by muse, mutect2, varscan2
- USF3 | c.3408A>T p.A1136= | Silent (SNP) | VAF 32/475 reads (7%) | catalogued as COSV57072566; called by muse, mutect2
- AUTS2 | c.624+69G>C | Intron (SNP) | VAF 26/90 reads (29%) | called by muse, varscan2
- CALCOCO2 | c.825+76T>A | Intron (SNP) | VAF 10/154 reads (6%) | called by muse, mutect2
- CRIPT | c.*53T>A | 3'UTR (SNP) | VAF 60/572 reads (10%) | called by muse, varscan2
- LINC02694 | n.551T>C | RNA (SNP) | VAF 17/224 reads (8%) | called by muse, mutect2
- TMEM178B | c.*32A>T | 3'UTR (SNP) | VAF 9/210 reads (4%) | called by muse, mutect2
